Gene-level copy-number profile of tumor specimen SM-JU33P from CPTAC case C243048, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen SM-JU33P: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8d00cd29-0480-4481-8ea2-de2817730986.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105206 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,251 have no estimate.
https://portal.gdc.cancer.gov/files/d33f5208-a75c-4f37-b678-f464ed7176b5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 5,647; copy number 2: 47,916; copy number 3: 3,588; copy number 4: 1,042; copy number 5: 76; copy number 6: 50; copy number 7: 2; copy number 8: 1; copy number 9: 2; copy number 10: 44.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,846,811–18,894,407, 4 genes: AC008132.1, BCRP7, FAM230F, AC008103.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 175 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes, copy number 9: AC239859.2, LINC02799.
- chr1:143,736,066–143,883,575, 9 genes, copy number 5–7 (within-gene range 3–7): AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP.
- chr1:143,955,364–144,373,659, 10 genes, copy number 5: FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr18:31,447,741–36,780,055, 93 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr18:38,655,209–39,800,322, 11 genes, copy number 5: AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P.
- chr19:567,210–1,228,431, 46 genes, copy number 6–10 (within-gene range 3–10): AC009005.1, BSG, HCN2, AC005559.1, POLRMT, AC004449.1, FGF22, RNF126, AC004156.1, FSTL3, PRSS57, RPS2P52, PALM, MISP, AC006273.1, LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2, STK11, HMGB2P1.
- chr19:5,158,495–5,340,803, 1 gene, copy number 5 (within-gene range 3–5): PTPRS.
- chr19:5,277,734–5,456,856, 3 genes, copy number 5–7: RPL32P34, AC005790.1, ZNRF4.

Autosomal genes at a single copy (total copy number 1): 5,647. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
